Somatic mutation profile of tumor specimen 2f398497-d53e-4838-8006-d60f3e (aliquot 2f398497-d53e-4838-8006-d60f3e_D6_1) from CPTAC case 20BR005, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 47.3 years (17,276 days).
Specimen 2f398497-d53e-4838-8006-d60f3e: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4dd8017f-cda4-426b-828e-72eaa27f5721.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 36b40856-2603-4e84-a7a1-e12e6f (Blood Derived Normal), aliquot 36b40856-2603-4e84-a7a1-e12e6f_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b3d9f6c-c6c8-4536-bef4-664ec07e04d1

The open-access MAF lists 173 somatic variants for this specimen: 119 protein-altering or splice-affecting, 35 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 90, Silent 35, Frame Shift Del 10, Splice Site 6, Nonsense Mutation 6, 5'UTR 5, Intron 4, 5'Flank 3, RNA 3, 3'UTR 3, In Frame Del 3, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAR | c.3193G>C p.V1065L | Missense Mutation (SNP) | VAF 163/823 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.193); catalogued as rs199708009; called by muse, mutect2, varscan2
- BHMG1 | c.673C>G p.P225A | Missense Mutation (SNP) | VAF 82/397 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.131); catalogued as rs559145513; called by muse, mutect2, varscan2
- CCDC59 | c.654G>T p.K218N | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV99810655; called by muse, mutect2, varscan2
- CDHR2 | c.1274G>C p.G425A | Missense Mutation (SNP) | VAF 72/368 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as rs760302877; called by muse, mutect2, varscan2
- CTTNBP2 | c.193C>G p.R65G | Missense Mutation (SNP) | VAF 28/257 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV50460790; called by muse, mutect2, varscan2
- CWF19L2 | c.833C>T p.T278M | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs148810189, COSV56514868; called by muse, varscan2
- EML6 | c.4129C>T p.R1377* | Nonsense Mutation (SNP) | VAF 34/159 reads (21%) | catalogued as rs941625901; called by muse, mutect2, varscan2
- ERCC6 | c.2594G>A p.R865K | Missense Mutation (SNP) | VAF 66/364 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.288); catalogued as rs762980922; called by muse, mutect2, varscan2
- FLG2 | c.4103A>C p.Q1368P | Missense Mutation (SNP) | VAF 91/864 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV66167142; called by muse, mutect2, varscan2
- GALNTL5 | c.565C>G p.L189V | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.752); catalogued as COSV67180324; called by muse, mutect2, varscan2
- GGN | c.706G>C p.E236Q | Missense Mutation (SNP) | VAF 97/296 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as rs1049423842; called by muse, mutect2, varscan2
- H4C3 | c.167G>C p.R56P | Missense Mutation (SNP) | VAF 48/329 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV58090203; called by muse, mutect2, varscan2
- IL21R | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.12); catalogued as rs913689113, COSV61968895; called by muse, mutect2, varscan2
- LIPE | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 55/288 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.039); catalogued as COSV54923399; called by muse, mutect2, varscan2
- MARVELD1 | c.127G>C p.A43P | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.805); catalogued as rs1290371056; called by muse, mutect2, varscan2
- MAS1L | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 42/325 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.162); catalogued as rs267600937, COSV65809177; called by muse, mutect2, varscan2
- MDC1 | c.3367G>A p.A1123T | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.046); catalogued as COSV64526492; called by muse, mutect2, varscan2
- MGAT4C | c.757G>C p.E253Q | Missense Mutation (SNP) | VAF 51/456 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100152874; called by muse, mutect2, varscan2
- MYH14 | c.1057C>G p.R353G | Missense Mutation (SNP) | VAF 58/252 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV51825333; called by muse, mutect2
- MYH9 | c.5058G>C p.Q1686H | Missense Mutation (SNP) | VAF 105/931 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as rs753622711; called by muse, mutect2, varscan2
- PCF11 | c.2923del p.Q975Nfs*25 | Frame Shift Del (DEL) | VAF 55/264 reads (21%) | catalogued as COSV100018697, COSV53529288; called by mutect2, pindel, varscan2
- PLCE1 | c.3991G>A p.D1331N | Missense Mutation (SNP) | VAF 197/544 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.852); catalogued as rs372685240; called by muse, mutect2, varscan2
- PNISR | c.2417A>G p.*806Wext*4 | Nonstop Mutation (SNP) | VAF 21/72 reads (29%) | catalogued as COSV65080579; called by muse, mutect2, varscan2
- PTK2B | c.1373C>A p.T458N | Missense Mutation (SNP) | VAF 33/231 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs903951254; called by muse, mutect2, varscan2
- PTOV1 | c.1021C>G p.R341G | Missense Mutation (SNP) | VAF 71/209 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV55591501; called by muse, mutect2, varscan2
- RCAN1 | c.587-1G>A p.X196_splice | Splice Site (SNP) | VAF 24/69 reads (35%) | catalogued as rs1215043340; called by muse, mutect2, varscan2
- RGS8 | c.47G>T p.R16L (on ENST00000367556 / NM_001369564.2; = p.R34L on NM_033345.3) | Missense Mutation (SNP) | VAF 29/254 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs751078612; called by muse, mutect2, varscan2
- RNF148 | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 141/291 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.363); catalogued as rs372584162; called by muse, mutect2, varscan2
- SCAF8 | c.1985C>G p.S662W | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100781296; called by muse, mutect2, varscan2
- SHC1 | c.1210C>G p.P404A (on ENST00000368445 / NM_183001.5; = p.P294A on NM_003029.5) | Missense Mutation (SNP) | VAF 58/476 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV63534553; called by muse, mutect2, varscan2
- SI | c.4028T>C p.I1343T | Missense Mutation (SNP) | VAF 45/244 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); catalogued as rs779805310, COSV52266870; called by muse, mutect2, varscan2
- SRSF6 | c.703_714del p.R235_S238del | In Frame Del (DEL) | VAF 20/160 reads (13%) | catalogued as rs1028799421; called by mutect2, varscan2
- TRIM29 | c.1259G>A p.C420Y | Missense Mutation (SNP) | VAF 37/368 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV59281291; called by muse, mutect2, varscan2
- USHBP1 | c.1229G>A p.G410D | Missense Mutation (SNP) | VAF 36/226 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs767567532; called by mutect2, varscan2
- ZNF208 | c.7T>C p.S3P | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs1451713554; called by muse, mutect2, varscan2
- ADAMTS8 | c.1699G>C p.G567R | Missense Mutation (SNP) | VAF 86/410 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTSL3 | c.3027_3062del p.R1009_H1020del | In Frame Del (DEL) | VAF 108/509 reads (21%) | called by mutect2, pindel, varscan2
- ADNP | c.1578G>C p.K526N | Missense Mutation (SNP) | VAF 35/215 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ARHGAP4 | c.1464C>G p.F488L | Missense Mutation (SNP) | VAF 30/328 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2
- ARHGEF4 | c.1766G>C p.R589T | Missense Mutation (SNP) | VAF 126/513 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- C3orf20 | c.784C>G p.L262V | Missense Mutation (SNP) | VAF 39/192 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- C5 | c.3503T>A p.L1168Q | Missense Mutation (SNP) | VAF 247/433 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- CA9 | c.386C>G p.A129G | Missense Mutation (SNP) | VAF 46/93 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CASZ1 | c.3497+5G>C | Splice Region (SNP) | VAF 60/213 reads (28%) | called by muse, mutect2, varscan2
- CBARP | c.370C>T p.R124C (on ENST00000382477; = p.R130C on NM_152769.3) | Missense Mutation (SNP) | VAF 76/146 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCDC18 | c.3826C>T p.Q1276* (on ENST00000343253 / NM_001306076.1; = p.Q1277* on NM_206886.4) | Nonsense Mutation (SNP) | VAF 16/200 reads (8%) | called by muse, mutect2
- CCDC181 | c.118A>G p.M40V | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCND3 | c.664G>C p.G222R | Missense Mutation (SNP) | VAF 31/250 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CCNL2 | c.289-34_291del p.X97_splice | Splice Site (DEL) | VAF 31/79 reads (39%) | called by mutect2, pindel, varscan2
- CDHR3 | c.941A>G p.E314G | Missense Mutation (SNP) | VAF 31/268 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- CEP192 | c.55_56delinsA p.S19Nfs*46 | Frame Shift Del (DEL) | VAF 12/70 reads (17%) | called by pindel, varscan2*
- CHCHD4 | c.347G>C p.R116T (on ENST00000396914 / NM_001098502.2; = p.R129T on NM_144636.3) | Missense Mutation (SNP) | VAF 45/182 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- CHRNB3 | c.174del p.F58Lfs*3 | Frame Shift Del (DEL) | VAF 9/68 reads (13%) | called by mutect2, pindel, varscan2
- CRYBA1 | c.625T>C p.S209P | Missense Mutation (SNP) | VAF 73/217 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CRYM | c.674-1G>A p.X225_splice | Splice Site (SNP) | VAF 51/354 reads (14%) | called by muse, mutect2, varscan2
- CYP27B1 | c.43G>C p.V15L | Missense Mutation (SNP) | VAF 135/314 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- DIP2A | c.1376C>A p.A459D | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- DNAH5 | c.10446C>A p.C3482* | Nonsense Mutation (SNP) | VAF 58/603 reads (10%) | called by muse, mutect2
- DNM1L | c.832A>G p.N278D | Missense Mutation (SNP) | VAF 81/431 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ELN | c.1228G>C p.G410R | Missense Mutation (SNP) | VAF 100/758 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERC2 | c.2008G>C p.A670P | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- EXOC2 | c.1280T>C p.L427P | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- FAM25C | c.37C>G p.L13V | Missense Mutation (SNP) | VAF 46/347 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FES | c.2422A>C p.S808R | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- FHOD3 | c.3197C>G p.P1066R (on ENST00000359247 / NM_001281739.3; = p.P1083R on NM_025135.5) | Missense Mutation (SNP) | VAF 30/175 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- FLG | c.11834A>T p.Q3945L | Missense Mutation (SNP) | VAF 154/1880 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.283); called by muse, mutect2
- FREM2 | c.907T>A p.F303I | Missense Mutation (SNP) | VAF 77/259 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GINS1 | c.76G>C p.E26Q | Missense Mutation (SNP) | VAF 37/214 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- HERC2P3 | n.1574+1del | Splice Site (DEL) | VAF 186/794 reads (23%) | called by mutect2, varscan2
- HINFP | c.1188C>G p.Y396* | Nonsense Mutation (SNP) | VAF 58/393 reads (15%) | called by muse, mutect2, varscan2
- HIPK3 | c.2475C>G p.D825E | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HK3 | c.620G>T p.R207L | Missense Mutation (SNP) | VAF 43/168 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- HLA-DMA | c.30del p.L11Cfs*98 | Frame Shift Del (DEL) | VAF 28/245 reads (11%) | called by mutect2, pindel, varscan2
- HNF4G | c.838G>T p.D280Y (on ENST00000354370 / NM_001330561.2; = p.D327Y on NM_004133.5) | Missense Mutation (SNP) | VAF 50/548 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- KCNH5 | c.604A>C p.T202P | Missense Mutation (SNP) | VAF 41/203 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- KCNN3 | c.1110G>C p.M370I | Missense Mutation (SNP) | VAF 18/591 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0.205); called by muse, mutect2
- KRIT1 | c.287A>C p.K96T | Missense Mutation (SNP) | VAF 27/210 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- LARP4B | c.1442_1469del p.E481Vfs*2 | Frame Shift Del (DEL) | VAF 68/289 reads (24%) | called by mutect2, varscan2
- LPAR3 | c.918G>T p.K306N | Missense Mutation (SNP) | VAF 261/903 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRIG1 | c.2467G>T p.E823* | Nonsense Mutation (SNP) | VAF 40/195 reads (21%) | called by muse, mutect2
- MRPS27 | c.958G>C p.E320Q | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MTCL1 | c.2575G>C p.E859Q (on ENST00000306329 / NM_001378206.1; = p.E499Q on NM_015210.4) | Missense Mutation (SNP) | VAF 38/217 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- MUC17 | c.6298G>A p.G2100R | Missense Mutation (SNP) | VAF 77/331 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.429); called by muse, mutect2, varscan2
- NCOR2 | c.5579_5594del p.I1860Rfs*16 | Frame Shift Del (DEL) | VAF 57/310 reads (18%) | called by mutect2, pindel, varscan2
- NPAS2 | c.1393-4A>G | Splice Region (SNP) | VAF 61/255 reads (24%) | called by muse, mutect2, varscan2
- NRROS | c.225C>G p.H75Q | Missense Mutation (SNP) | VAF 58/293 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NTN4 | c.37T>C p.C13R | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.035); called by muse, varscan2
- NUTM1 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 58/247 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- OR5H2 | c.444_447del p.L149* | Frame Shift Del (DEL) | VAF 30/320 reads (9%) | called by mutect2, pindel
- PBDC1 | c.34T>C p.S12P | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PDE4A | c.976G>T p.V326L (on ENST00000380702 / NM_001111307.2; = p.V87L on NM_006202.3) | Missense Mutation (SNP) | VAF 63/433 reads (15%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDZK1IP1 | c.215C>A p.A72E | Missense Mutation (SNP) | VAF 65/325 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PHIP | c.1738C>A p.Q580K | Missense Mutation (SNP) | VAF 24/235 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); called by muse, mutect2
- PI15 | c.485C>G p.P162R | Missense Mutation (SNP) | VAF 91/542 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIWIL3 | c.585G>C p.L195F | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PLOD3 | c.948G>T p.Q316H | Missense Mutation (SNP) | VAF 89/653 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- PPIH | c.207_210del p.I69Mfs*4 | Frame Shift Del (DEL) | VAF 15/79 reads (19%) | called by mutect2, pindel, varscan2
- RPL7 | c.533C>G p.S178C | Missense Mutation (SNP) | VAF 34/159 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.592); called by muse, mutect2
- RRAGC | c.642-1G>T p.X214_splice | Splice Site (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
- SAMD4B | c.2074T>A p.S692T | Missense Mutation (SNP) | VAF 46/296 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- SEMA3B | c.1723C>G p.L575V | Missense Mutation (SNP) | VAF 112/353 reads (32%) | SIFT tolerated (0.67); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- SIAE | c.1474T>G p.C492G | Missense Mutation (SNP) | VAF 86/479 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- SLC35B2 | c.508T>C p.S170P | Missense Mutation (SNP) | VAF 48/443 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SLIT1 | c.4531G>C p.E1511Q | Missense Mutation (SNP) | VAF 71/488 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- SPAG17 | c.1990G>T p.D664Y | Missense Mutation (SNP) | VAF 112/391 reads (29%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- SPHKAP | c.3751G>C p.V1251L | Missense Mutation (SNP) | VAF 126/780 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); called by mutect2, varscan2
- SRGAP2C | c.779C>A p.T260N | Missense Mutation (SNP) | VAF 35/169 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SRSF6 | c.594_611del p.X198_splice | Splice Site (DEL) | VAF 21/133 reads (16%) | called by mutect2, varscan2
- STAB2 | c.3395_3417del p.R1132Pfs*10 | Frame Shift Del (DEL) | VAF 32/308 reads (10%) | called by mutect2, varscan2
- TBC1D22A | c.351_382del p.P118Rfs*18 | Frame Shift Del (DEL) | VAF 43/139 reads (31%) | called by mutect2, pindel, varscan2
- TBX18 | c.588C>A p.N196K | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- TTN | c.12754A>G p.S4252G (on ENST00000591111; = p.S4206G on NM_003319.4) | Missense Mutation (SNP) | VAF 22/478 reads (5%) | called by muse, mutect2
- UBR2 | c.4502G>C p.G1501A | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZHX3 | c.471_521del p.E157_A173del | In Frame Del (DEL) | VAF 47/377 reads (12%) | called by mutect2, pindel
- ZMYM6 | c.3536A>G p.N1179S | Missense Mutation (SNP) | VAF 50/96 reads (52%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF14 | c.1504C>A p.P502T | Missense Mutation (SNP) | VAF 180/439 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ZNF275 | c.53_58dup p.A18_L19dup | In Frame Ins (INS) | VAF 102/286 reads (36%) | called by mutect2, varscan2
- ZNF385D | c.1025C>G p.A342G | Missense Mutation (SNP) | VAF 28/211 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); called by muse, varscan2
- ZNF608 | c.3770C>G p.S1257* | Nonsense Mutation (SNP) | VAF 10/178 reads (6%) | called by muse, mutect2
- ANKRD18B | c.1980T>C p.N660= | Silent (SNP) | VAF 17/50 reads (34%) | called by muse, mutect2, varscan2
- APOL1 | c.771T>C p.F257= | Silent (SNP) | VAF 23/189 reads (12%) | called by muse, mutect2, varscan2
- ARAP2 | c.3300C>T p.F1100= | Silent (SNP) | VAF 30/87 reads (34%) | called by muse, mutect2, varscan2
- C9orf16 | c.147T>C p.N49= | Silent (SNP) | VAF 34/167 reads (20%) | catalogued as rs1460168468; called by mutect2, varscan2
- CARMIL1 | c.1200C>T p.S400= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as rs369443890; called by muse, mutect2, varscan2
- CCDC168 | c.10467C>G p.L3489= | Silent (SNP) | VAF 31/251 reads (12%) | catalogued as rs1283844617; called by muse, mutect2, varscan2
- CD164 | c.54C>G p.L18= | Silent (SNP) | VAF 16/138 reads (12%) | catalogued as rs938936993; called by muse, mutect2, varscan2
- CD70 | c.117G>A p.Q39= | Silent (SNP) | VAF 31/130 reads (24%) | called by muse, mutect2, varscan2
- CHL1 | c.3171C>T p.S1057= (on ENST00000397491 / NM_001253387.1; = p.S1073= on NM_006614.4) | Silent (SNP) | VAF 21/97 reads (22%) | called by muse, mutect2, varscan2
- COL5A1 | c.2619A>C p.P873= | Silent (SNP) | VAF 89/469 reads (19%) | called by muse, mutect2, varscan2
- COL6A5 | c.3972A>G p.S1324= | Silent (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2
- DLEC1 | c.27G>C p.R9= | Silent (SNP) | VAF 34/100 reads (34%) | called by muse, mutect2, varscan2
- ERO1B | c.159T>C p.N53= | Silent (SNP) | VAF 13/99 reads (13%) | catalogued as rs1431171635; called by muse, mutect2, varscan2
- FAM98C | c.402G>A p.L134= | Silent (SNP) | VAF 70/449 reads (16%) | called by muse, mutect2, varscan2
- ITPR3 | c.102C>T p.D34= | Silent (SNP) | VAF 24/166 reads (14%) | catalogued as rs1419981911; called by muse, mutect2, varscan2
- KAT6B | c.525T>C p.N175= | Silent (SNP) | VAF 38/236 reads (16%) | called by muse, mutect2, varscan2
- MADD | c.69G>A p.P23= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as rs200598460, COSV60621685; called by muse, mutect2, varscan2
- MUC4 | c.15828C>G p.V5276= (on ENST00000463781 / NM_018406.7; = p.V1040= on NM_004532.6) | Silent (SNP) | VAF 71/285 reads (25%) | called by muse, mutect2, varscan2
- NPAP1 | c.957A>G p.R319= | Silent (SNP) | VAF 60/535 reads (11%) | called by muse, mutect2, varscan2
- OR2A5 | c.168C>A p.T56= | Silent (SNP) | VAF 62/426 reads (15%) | called by muse, mutect2, varscan2
- PCDHA3 | c.2205C>G p.G735= | Silent (SNP) | VAF 137/266 reads (52%) | catalogued as rs782398049; called by mutect2, varscan2
- PHACTR1 | c.1254C>G p.V418= | Silent (SNP) | VAF 26/204 reads (13%) | called by muse, mutect2, varscan2
- PPP6C | c.105C>G p.L35= | Silent (SNP) | VAF 7/42 reads (17%) | called by mutect2, varscan2
- RBFOX2 | c.1218T>G p.A406= (on ENST00000438146 / NM_001349995.2; = p.L319R on NM_014309.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/164 reads (7%) | called by muse, mutect2
- RELN | c.9855C>G p.T3285= | Silent (SNP) | VAF 104/777 reads (13%) | catalogued as COSV100632299; called by muse, mutect2, varscan2
- SALL1 | c.369G>A p.E123= | Silent (SNP) | VAF 121/573 reads (21%) | catalogued as COSV51759695; called by muse, mutect2, varscan2
- SCUBE1 | c.2826G>A p.L942= | Silent (SNP) | VAF 22/132 reads (17%) | called by muse, mutect2, varscan2
- SEPTIN2 | c.210A>G p.G70= | Silent (SNP) | VAF 43/252 reads (17%) | called by muse, mutect2, varscan2
- SLC66A3 | c.405T>C p.C135= | Silent (SNP) | VAF 22/161 reads (14%) | called by muse, mutect2, varscan2
- SNAP29 | c.768A>G p.R256= | Silent (SNP) | VAF 63/362 reads (17%) | called by muse, mutect2, varscan2
- TENM1 | c.1233C>A p.T411= | Silent (SNP) | VAF 56/207 reads (27%) | called by muse, mutect2, varscan2
- USHBP1 | c.1230C>G p.G410= | Silent (SNP) | VAF 36/231 reads (16%) | called by mutect2, varscan2
- VN1R1 | c.450C>G p.L150= | Silent (SNP) | VAF 42/192 reads (22%) | catalogued as COSV100320750; called by muse, mutect2, varscan2
- YTHDF1 | c.474G>A p.L158= | Silent (SNP) | VAF 71/308 reads (23%) | catalogued as rs779225850; called by muse, mutect2, varscan2
- ZEB2 | c.3294A>G p.K1098= | Silent (SNP) | VAF 31/122 reads (25%) | catalogued as COSV57962385; called by muse, mutect2, varscan2
- ADIG | c.*406C>T | 3'UTR (SNP) | VAF 25/138 reads (18%) | catalogued as rs1482320523; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504217 G>C | 5'Flank (SNP) | VAF 24/77 reads (31%) | called by muse, mutect2, varscan2
- APOB | c.2436+106T>G | Intron (SNP) | VAF 16/95 reads (17%) | called by muse, mutect2, varscan2
- CA2 | c.-74C>G | 5'UTR (SNP) | VAF 23/216 reads (11%) | called by muse, mutect2, varscan2
- DALRD3 | chr3:49020214 G>C | 5'Flank (SNP) | VAF 26/135 reads (19%) | called by muse, mutect2, varscan2
- DBF4B | c.*694C>T | 3'UTR (SNP) | VAF 40/239 reads (17%) | called by muse, mutect2, varscan2
- DSE | c.-45G>C | 5'UTR (SNP) | VAF 27/177 reads (15%) | catalogued as COSV59066147; called by muse, mutect2, varscan2
- ENO3 | c.85+148G>C | Intron (SNP) | VAF 60/342 reads (18%) | catalogued as COSV56698108; called by muse, mutect2, varscan2
- FBXL21P | n.949A>G | RNA (SNP) | VAF 28/82 reads (34%) | called by muse, varscan2
- FOSL2 | c.463-31T>A | Intron (SNP) | VAF 51/207 reads (25%) | called by muse, mutect2, varscan2
- IMPDH2 | chr3:49029515 G>C | 5'Flank (SNP) | VAF 48/159 reads (30%) | called by muse, mutect2, varscan2
- KIR3DX1 | n.93T>C | RNA (SNP) | VAF 49/262 reads (19%) | called by muse, mutect2, varscan2
- MARVELD3 | chr16:71640615 C>T | 3'Flank (SNP) | VAF 94/420 reads (22%) | called by muse, varscan2
- STX1A | c.678+94dup | Intron (INS) | VAF 70/276 reads (25%) | called by mutect2, varscan2
- TMEM186 | chr16:8797631 del GCCGGAAGTAAATCCCA | 5'UTR (DEL) | VAF 14/70 reads (20%) | called by mutect2, pindel, varscan2
- USH2A | c.-33G>T | 5'UTR (SNP) | VAF 35/190 reads (18%) | catalogued as COSV100240720; called by muse, mutect2, varscan2
- VKORC1L1 | c.*25G>C | 3'UTR (SNP) | VAF 31/161 reads (19%) | called by muse, mutect2, varscan2
- ZNF335 | c.-105A>G | 5'UTR (SNP) | VAF 30/189 reads (16%) | catalogued as rs922176425; called by muse, mutect2, varscan2
- ZNF503-AS2 | n.436C>A | RNA (SNP) | VAF 118/433 reads (27%) | called by muse, mutect2, varscan2
